Somatic mutation profile of tumor specimen TCGA-D6-8568-01A (aliquot TCGA-D6-8568-01A-11D-2394-08) from TCGA case TCGA-D6-8568, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 62.4 years (22,796 days).
Specimen TCGA-D6-8568-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95d6c4c0-361e-441b-ade7-d1ee0fa5ec44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-8568-10A (Blood Derived Normal), aliquot TCGA-D6-8568-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85f19e42-43cb-444e-a258-c4364460dfa2

The open-access MAF lists 116 somatic variants for this specimen: 94 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 20, Nonsense Mutation 7, Frame Shift Del 6, Frame Shift Ins 3, Splice Site 2, 3'UTR 1, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.487T>C p.Y163H | Missense Mutation (SNP) | VAF 46/124 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADAM7 | c.1129C>A p.Q377K | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV99443900; called by muse, mutect2
- ADGRL4 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100875946, COSV66066425; called by mutect2, varscan2
- ALX3 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV100873879; called by muse, varscan2
- ANO5 | c.2225T>A p.V742D | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100201841; called by muse, mutect2, varscan2
- ARHGAP10 | c.1462C>G p.P488A | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.22); catalogued as COSV100331225; called by muse, mutect2, varscan2
- ARMC3 | c.1994C>G p.S665C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV99958059; called by muse, mutect2, varscan2
- CAMK2G | c.401A>G p.H134R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV59483151; called by muse, mutect2, varscan2
- CD40 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100953835; called by muse, mutect2, varscan2
- CDH19 | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs754909023, COSV100051559; called by muse, mutect2, varscan2
- CES2 | c.1473G>A p.W491* | Nonsense Mutation (SNP) | VAF 48/121 reads (40%) | catalogued as COSV100399234; called by muse, mutect2, varscan2
- COX10 | c.254A>G p.E85G | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV99886431; called by muse, mutect2, varscan2
- CRYBB1 | c.673C>G p.Q225E | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99316027; called by muse, mutect2, varscan2
- DLC1 | c.2036C>G p.S679C (on ENST00000276297 / NM_001348081.2; = p.S242C on NM_006094.5) | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV99363087; called by muse, mutect2, varscan2
- DMBT1 | c.6170G>T p.G2057V (on ENST00000338354 / NM_001377530.1; = p.G1300V on NM_004406.3) | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100352918, COSV57533673, COSV57559889; called by muse, mutect2, varscan2
- DPY19L4 | c.775T>A p.F259I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101363282; called by muse, mutect2, varscan2
- DSCAM | c.68G>T p.S23I | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV101260098; called by muse, mutect2, varscan2
- DSP | c.1506C>G p.D502E | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.083); catalogued as COSV101131276; called by muse, mutect2, varscan2
- EBNA1BP2 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 39/278 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV99355943; called by muse, mutect2, varscan2
- EEF2K | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV99533140; called by muse, mutect2, varscan2
- EMC2 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | catalogued as COSV55208384; called by muse, mutect2
- F8 | c.1276T>C p.Y426H | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100811517; called by muse, mutect2, varscan2
- FANCA | c.792G>A p.Q264= | Splice Region (SNP) | VAF 22/163 reads (13%) | catalogued as COSV101224775; called by muse, mutect2, varscan2
- GCNT2 | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101097399, COSV101097774; called by muse, mutect2, varscan2
- GFRA2 | c.255G>T p.L85F | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1042790931; called by muse, mutect2
- GPR149 | c.939G>T p.L313F | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV101078433; called by muse, mutect2, varscan2
- HIKESHI | c.540G>A p.W180* | Nonsense Mutation (SNP) | VAF 3/41 reads (7%) | catalogued as COSV99563418; called by muse, mutect2
- HIPK4 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs763886506, COSV99396657; called by muse, mutect2, varscan2
- HIVEP2 | c.4928C>G p.T1643R | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99173398; called by muse, mutect2, varscan2
- IPPK | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99845614; called by muse, mutect2, varscan2
- KANSL1 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52264650; called by muse, mutect2, varscan2
- KDM6A | c.3378A>G p.I1126M | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100938182; called by muse, mutect2, varscan2
- KIF21A | c.3461G>C p.R1154P (on ENST00000361418 / NM_001378440.1; = p.R1141P on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV100735457, COSV62772282; called by muse, mutect2, varscan2
- KMT2D | c.8167G>T p.E2723* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99981619; called by muse, mutect2, varscan2
- LIPF | c.816+1G>T p.X272_splice | Splice Site (SNP) | VAF 24/129 reads (19%) | catalogued as COSV99490302; called by muse, mutect2, varscan2
- LRRTM1 | c.544C>A p.Q182K | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV54443502, COSV99702511; called by muse, mutect2, varscan2
- LRRTM4 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs760929307, COSV101297465; called by muse, mutect2, varscan2
- LVRN | c.2408C>T p.S803L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV100773455; called by muse, mutect2, varscan2
- MAP6 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100496667; called by muse, mutect2, varscan2
- METAP1D | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV100249922; called by muse, mutect2, varscan2
- MPRIP | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV100505694; called by muse, mutect2, varscan2
- NIPBL | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1326545778, COSV56958901, COSV99242711; called by muse, mutect2, varscan2
- NOA1 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV99950520; called by muse, mutect2, varscan2
- NUDT1 | c.404C>T p.P135L (on ENST00000397048 / NM_198952.1; = p.P112L on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/379 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV99770829; called by muse, mutect2, varscan2
- NUP155 | c.995+1G>C p.X332_splice (on ENST00000231498 / NM_153485.3; = p.X273_splice on NM_004298.4) | Splice Site (SNP) | VAF 13/145 reads (9%) | catalogued as COSV99192848; called by muse, mutect2
- OBI1 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as COSV99932460; called by muse, mutect2, varscan2
- OR52J3 | c.233C>A p.T78N | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV100984871; called by muse, mutect2, varscan2
- OR5H1 | c.632T>C p.I211T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100641692; called by muse, mutect2, varscan2
- PAQR7 | c.127T>A p.W43R | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100961671; called by muse, mutect2, varscan2
- PBRM1 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV99968754; called by muse, mutect2, varscan2
- PCDHB8 | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 54/811 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as COSV99176930; called by muse, mutect2
- PCDHGC4 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs762408704, COSV99340032; called by muse, mutect2, varscan2
- PEG3 | c.3098G>T p.C1033F | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99687437, COSV99690839; called by muse, mutect2, varscan2
- PPIG | c.2100A>C p.E700D | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.584); catalogued as COSV99644534; called by muse, mutect2, varscan2
- PRX | c.4349C>A p.P1450Q | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as COSV99396659; called by muse, mutect2, varscan2
- PTCH2 | c.3181C>T p.P1061S | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100807951; called by muse, mutect2, varscan2
- PTPRB | c.4513C>T p.Q1505* | Nonsense Mutation (SNP) | VAF 31/215 reads (14%) | catalogued as COSV99717350; called by muse, mutect2, varscan2
- RGS3 | c.3049G>A p.E1017K (on ENST00000350696 / NM_001282923.2; = p.E736K on NM_130795.4) | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs368247804; called by muse, mutect2, varscan2
- RS1 | c.107A>C p.K36T | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.469); catalogued as COSV101183799; called by muse, mutect2, varscan2
- SARAF | c.889C>G p.P297A | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs754106182, COSV56357275, COSV99822742; called by muse, mutect2, varscan2
- SH3GL2 | c.754A>T p.R252* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV101014347; called by muse, mutect2, varscan2
- SLC25A42 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100588070, COSV59380912; called by muse, mutect2, varscan2
- SLC35E3 | c.636A>T p.E212D | Missense Mutation (SNP) | VAF 53/269 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV100098023; called by muse, mutect2, varscan2
- SLC35F1 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as rs140419570; called by muse, mutect2, varscan2
- SLC4A8 | c.1759T>C p.C587R | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.976); catalogued as COSV100176873; called by muse, mutect2, varscan2
- SMARCAD1 | c.2913A>T p.E971D | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV100758915; called by muse, mutect2, varscan2
- SRGAP1 | c.3053G>A p.R1018K | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV100754679; called by muse, varscan2
- STAT6 | c.484C>G p.L162V | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.315); catalogued as COSV100273324, COSV55674411; called by muse, mutect2, varscan2
- TCHHL1 | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV100916534; called by muse, mutect2, varscan2
- THEG | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1287035353, COSV100700607; called by muse, mutect2
- TMEM132A | c.2587A>T p.I863F (on ENST00000453848 / NM_178031.3; = p.I864F on NM_017870.4) | Missense Mutation (SNP) | VAF 60/325 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99135164; called by muse, mutect2, varscan2
- TMEM200C | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1422402189, COSV67309340; called by muse, mutect2, varscan2
- TPPP3 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs368634690; called by muse, mutect2, varscan2
- TTN | c.33054A>T p.K11018N (on ENST00000591111; = p.K10091N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | PolyPhen benign (0.006); catalogued as COSV100611967; called by muse, mutect2, varscan2
- UCP1 | c.351T>G p.I117M | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV99530262; called by muse, mutect2, varscan2
- USP7 | c.1664G>A p.R555Q | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61215419; called by muse, mutect2, varscan2
- XIRP1 | c.421C>A p.Q141K | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as COSV100453633; called by muse, mutect2, varscan2
- YY1 | c.254C>G p.A85G | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99216807; called by muse, mutect2, varscan2
- ZNF404 | c.687C>G p.H229Q | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as COSV100182554; called by muse, mutect2, varscan2
- ZNF507 | c.1450A>G p.R484G | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100321822; called by muse, mutect2, varscan2
- ZNF678 | c.461A>C p.K154T (on ENST00000343776 / NM_001367910.1; = p.K209T on NM_178549.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as COSV100652766; called by muse, mutect2, varscan2
- ZNF804B | c.1127G>A p.S376N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV100303759, COSV60862576; called by muse, mutect2, varscan2
- AJUBA | c.1293_1298delinsG p.C432Qfs*29 | Frame Shift Del (DEL) | VAF 35/114 reads (31%) | called by pindel, varscan2*
- BTBD8 | c.1072del p.I358Yfs*13 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- BUB1B | c.1719_1720del p.P575Rfs*4 | Frame Shift Del (DEL) | VAF 19/142 reads (13%) | called by pindel, varscan2
- CENPM | c.525del p.S176Pfs*28 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel, varscan2
- CRYBG3 | c.8597del p.C2866Sfs*31 | Frame Shift Del (DEL) | VAF 23/130 reads (18%) | called by mutect2, pindel, varscan2
- DAG1 | c.1064_1074del p.A355Efs*82 | Frame Shift Del (DEL) | VAF 46/209 reads (22%) | called by mutect2, pindel, varscan2
- GPR179 | c.6307G>A p.E2103K (on ENST00000621958; = p.E2102K on NM_001004334.4) | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- MARK2 | c.1054_1056del p.N352del | In Frame Del (DEL) | VAF 17/132 reads (13%) | called by mutect2, pindel, varscan2
- PFN1 | c.291dup p.T98Hfs*10 | Frame Shift Ins (INS) | VAF 33/188 reads (18%) | called by mutect2, pindel, varscan2
- TCF7L1 | c.1584_1587dup p.S531Lfs*71 | Frame Shift Ins (INS) | VAF 13/97 reads (13%) | called by mutect2, pindel, varscan2
- UBE2NL | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- UCK2 | c.213dup p.Q72Afs*13 | Frame Shift Ins (INS) | VAF 20/99 reads (20%) | called by mutect2, pindel, varscan2
- ADAMTS8 | c.1977C>T p.G659= | Silent (SNP) | VAF 10/162 reads (6%) | catalogued as COSV99960923; called by muse, mutect2
- AXIN1 | c.141G>T p.G47= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as COSV51983610, COSV99249773; called by muse, mutect2, varscan2
- CCND1 | c.630C>T p.A210= | Silent (SNP) | VAF 39/315 reads (12%) | catalogued as rs146267501; called by muse, mutect2, varscan2
- COL6A6 | c.5331G>A p.K1777= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100650248; called by muse, mutect2
- FLRT3 | c.1306T>C p.L436= | Silent (SNP) | VAF 33/171 reads (19%) | catalogued as rs1199291152, COSV99432495; called by muse, mutect2, varscan2
- HSPA12B | c.846T>G p.R282= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV99653993; called by muse, mutect2, varscan2
- KRT6A | c.1071G>A p.Q357= | Silent (SNP) | VAF 58/304 reads (19%) | catalogued as COSV100416977; called by muse, mutect2, varscan2
- LRRC8A | c.735G>A p.E245= | Silent (SNP) | VAF 23/156 reads (15%) | catalogued as COSV52189508, COSV99396581; called by muse, mutect2, varscan2
- LYPLAL1 | c.210A>G p.K70= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100859691; called by muse, mutect2, varscan2
- NAA30 | c.294C>G p.A98= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV100035879; called by muse, mutect2, varscan2
- NRROS | c.1596C>T p.F532= | Silent (SNP) | VAF 58/378 reads (15%) | catalogued as COSV100145485; called by muse, mutect2, varscan2
- PCSK5 | c.5403C>T p.S1801= | Silent (SNP) | VAF 52/243 reads (21%) | catalogued as rs1168453993, COSV101377380; called by muse, mutect2, varscan2
- POMT2 | c.1983C>G p.L661= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as COSV99836397; called by muse, mutect2, varscan2
- PROS1 | c.567T>A p.G189= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100820296; called by muse, mutect2, varscan2
- RAB6C | c.30G>A p.P10= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV69339462; called by mutect2, varscan2
- RAG2 | c.1032T>C p.Y344= | Silent (SNP) | VAF 42/159 reads (26%) | catalogued as COSV100271297; called by muse, mutect2, varscan2
- RO60 | c.756A>G p.R252= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100814377; called by muse, mutect2, varscan2
- SAMD4A | c.597C>T p.C199= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as rs1419047191, COSV99200668; called by muse, mutect2, varscan2
- TIAM2 | c.3828G>C p.L1276= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV51643365, COSV99265516; called by muse, mutect2
- UBXN6 | c.720C>T p.Y240= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as rs145906971; called by muse, mutect2, varscan2
- RNF217-AS1 | n.3282A>G | RNA (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- TMEM125 | c.*2G>A | 3'UTR (SNP) | VAF 6/41 reads (15%) | catalogued as rs770449916, COSV101443201; called by muse, mutect2, varscan2
